Gene-level copy-number profile of tumor specimen HCM-BROD-0234-C49-06A from HCMI case HCM-BROD-0234-C49, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Spindle cell sarcoma; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G4; Age at diagnosis: 76.5 years (27,950 days).
Specimen HCM-BROD-0234-C49-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 04d006e2-10fa-4c8d-88cf-fd3eabc5de0d.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-BROD-0234-C49-10B (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,758 have no estimate.
https://portal.gdc.cancer.gov/files/8526f1d9-0ecd-43bf-86b6-aee00a8f186b

Most common (modal) total copy number across autosomal genes: 5 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 6; copy number 1: 24; copy number 2: 1,957; copy number 3: 9,954; copy number 4: 11,291; copy number 5: 17,093; copy number 6: 11,312; copy number 7: 5,375; copy number 8: 1,345; copy number 9: 113; copy number 10: 249; copy number 11: 11; copy number 12: 17; copy number 25: 23; copy number 32: 27; copy number 41: 7; copy number 45: 22; copy number 46: 2; copy number 47: 6; copy number 54: 31.

Homozygous deletions (total copy number 0; autosomes only): 6 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:25,242,249–25,338,213, 6 genes (within-gene range 0–5): RSRP1, AL031432.3, AL031432.2, RHD, SDHDP6, AL928711.1.

Amplified relative to the modal value (total copy number ≥ 11, i.e. more than twice the modal value of 5; autosomes only): 146 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:48,710,789–52,022,974, 30 genes, copy number 12–47: EFCAB1, AC013701.1, SNAI2, AC044893.2, PPDPFL, AC044893.1, RN7SKP294, RFPL4AP7, AC090155.2, AC090155.1, PSAT1P1, AC113145.1, AC023762.1, SNTG1, AC090539.1, AC090539.2, CYCSP22, AC087272.1, AC090919.1, AC012413.1, PXDNL, BRIX1P1, BTF3P1, AC090186.1, PCMTD1, AC103769.1, AC064807.1, AC064807.4, AC064807.2, AC064807.3.
- chr9:100,302,077–101,325,135, 11 genes, copy number 11 (within-gene range 8–11): TEX10, MSANTD3, MSANTD3-TMEFF1, TMEFF1, CAVIN4, RN7SKP87, ACTG1P19, AL162395.1, GAPDHP26, PLPPR1, AL161631.1.
- chr11:28,702,607–31,369,810, 25 genes, copy number 25–46 (within-gene range 4–46): LINC02742, OR2BH1P, AC090791.1, AC110056.1, LINC02755, AC090124.2, AC090124.1, AC110058.1, LINC02546, HNRNPRP2, AC107973.1, RN7SL240P, RPL7AP58, LINC01616, KCNA4, AL358944.1, AL358944.2, FSHB, ARL14EP, RPL12P30, MPPED2, AL353699.1, MPPED2-AS1, AL122014.1, DCDC1.
- chr11:31,812,307–35,530,300, 80 genes, copy number 32–54 (within-gene range 5–54) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 5. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
